Somatic mutation profile of tumor specimen TCGA-44-A4SU-01A (aliquot TCGA-44-A4SU-01A-11D-A24P-08) from TCGA case TCGA-44-A4SU, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 68.0 years (24,820 days).
Specimen TCGA-44-A4SU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9e730a8-0442-4679-8154-4bc09b39e16a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-A4SU-10A (Blood Derived Normal), aliquot TCGA-44-A4SU-10A-01D-A24P-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94654125-5390-4d38-9c65-93c24c8268ce

The open-access MAF lists 153 somatic variants for this specimen: 113 protein-altering or splice-affecting, 38 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 38, Nonsense Mutation 7, Frame Shift Del 3, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2155G>T p.G719C | Missense Mutation (SNP) | VAF 68/118 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28929495, COSV51766606, COSV51767289; ClinVar: pathogenic / drug response / likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2303G>T p.S768I | Missense Mutation (SNP) | VAF 134/239 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913465, COSV51768106, COSV51821681, COSV51833841; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.159G>A p.W53* | Nonsense Mutation (SNP) | VAF 127/250 reads (51%) | hotspot (GDC flag); catalogued as rs1064794618, COSV52751414, COSV53223969, COSV53499187; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.4848G>T p.W1616C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100383293; called by muse, mutect2, varscan2
- AC005833.1 | c.1534T>C p.Y512H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated, low confidence (0.44); catalogued as COSV99363018; called by muse, mutect2, varscan2
- ADAMTS3 | c.2523G>T p.Q841H | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.572); catalogued as COSV99711549; called by muse, mutect2, varscan2
- ADCY2 | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100603374; called by muse, mutect2, varscan2
- ADGRB3 | c.2110G>T p.A704S | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV101001148; called by muse, varscan2
- AL121899.2 | c.635T>A p.L212* | Nonsense Mutation (SNP) | VAF 62/295 reads (21%) | catalogued as COSV101198566; called by muse, mutect2, varscan2
- ALAS2 | c.525T>A p.Y175* | Nonsense Mutation (SNP) | VAF 22/96 reads (23%) | catalogued as COSV100238479; called by muse, mutect2, varscan2
- ASB11 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100729087; called by muse, mutect2
- ATRX | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV100969580; called by muse, mutect2, varscan2
- BBS9 | c.75G>T p.L25F | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99629170; called by muse, mutect2, varscan2
- BCL6B | c.305G>T p.R102L | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV99546783; called by muse, mutect2, varscan2
- BMP1 | c.105G>C p.E35D | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.216); catalogued as COSV59244224; called by muse, mutect2, varscan2
- C7orf31 | c.1548G>A p.M516I | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV99384051; called by muse, mutect2
- CACNA1C | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs752000790, COSV59707966; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- CLCN1 | c.2692G>T p.G898W | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV100578257; called by muse, mutect2, varscan2
- COL4A1 | c.689A>G p.D230G | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as COSV101011331; called by muse, mutect2, varscan2
- DOCK3 | c.5870C>G p.S1957* | Nonsense Mutation (SNP) | VAF 13/65 reads (20%) | catalogued as COSV99813552; called by muse, mutect2, varscan2
- DSEL | c.951G>T p.W317C | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59490379; called by muse, mutect2, varscan2
- ERICH3 | c.2833A>T p.S945C | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.752); catalogued as COSV100444988; called by muse, mutect2, varscan2
- F13A1 | c.2001C>A p.H667Q | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); catalogued as COSV99343476; called by muse, mutect2, varscan2
- FGD5 | c.3241G>T p.A1081S | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV99548623; called by muse, mutect2, varscan2
- FLG | c.1859G>T p.S620I | Missense Mutation (SNP) | VAF 95/515 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774082958, COSV100911806; called by muse, mutect2, varscan2
- FRMPD4 | c.1455C>A p.H485Q | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as COSV101043400, COSV66212334; called by muse, mutect2, varscan2
- GALR3 | c.52G>A p.V18M | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as rs200165050; called by muse, mutect2, varscan2
- GDPD2 | c.850G>C p.V284L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as COSV100978657; called by muse, mutect2, varscan2
- GPR137C | c.1198G>A p.G400R | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772449876, COSV100397729; called by muse, mutect2, varscan2
- GRIK1 | c.2378T>G p.I793S | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100517322; called by muse, mutect2, varscan2
- GRIK4 | c.655G>C p.A219P | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV101483661, COSV70800914; called by muse, mutect2, varscan2
- GYG2 | c.1429G>T p.E477* | Nonsense Mutation (SNP) | VAF 26/48 reads (54%) | catalogued as COSV100089136; called by muse, mutect2, varscan2
- HECW1 | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67836695; called by muse, mutect2, varscan2
- HSPA12B | c.2003C>A p.A668D | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99422332; called by muse, mutect2
- HYKK | c.1094A>T p.K365I | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as COSV101195088; called by muse, mutect2
- IL12RB2 | c.7C>A p.H3N | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.051); catalogued as COSV99255403; called by muse, mutect2, varscan2
- KALRN | c.5906G>A p.R1969Q (on ENST00000360013 / NM_001024660.4; = p.R272Q on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as rs186931113, COSV99362464; called by muse, mutect2
- KCNQ4 | c.1582C>A p.P528T | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100714377; called by muse, mutect2, varscan2
- KDR | c.1774C>T p.P592S | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV99818174; called by muse, mutect2, varscan2
- KIAA1586 | c.1490A>G p.H497R | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs201387216, COSV100875369; called by muse, mutect2, varscan2
- KLK13 | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 21/222 reads (9%) | catalogued as rs536078012, COSV50067335, COSV99335170; called by muse, mutect2
- LHX8 | c.980A>G p.H327R | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1185601695, COSV99634042; called by muse, mutect2
- LIN28B | c.550T>A p.S184T | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.049); catalogued as COSV100558940; called by muse, mutect2, varscan2
- LMAN2L | c.25G>T p.G9W | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99383484; called by muse, mutect2, varscan2
- LRFN5 | c.788G>T p.C263F | Missense Mutation (SNP) | VAF 39/284 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99984629; called by muse, mutect2, varscan2
- MGA | c.9181A>C p.S3061R (on ENST00000219905 / NM_001164273.1; = p.S2852R on NM_001080541.2) | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.157); catalogued as COSV99580647; called by muse, mutect2, varscan2
- MS4A14 | c.1984C>A p.Q662K | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.354); catalogued as COSV100280561; called by muse, mutect2, varscan2
- MUC16 | c.30626C>A p.T10209K | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.06); catalogued as COSV101200493; called by muse, mutect2, varscan2
- MUC17 | c.7526C>T p.T2509I | Missense Mutation (SNP) | VAF 26/656 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV100074221, COSV60291284; called by muse, mutect2
- MXRA5 | c.8032C>T p.H2678Y | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV99478013; called by muse, mutect2, varscan2
- MYH4 | c.1474T>C p.F492L | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as COSV99701704; called by muse, mutect2, varscan2
- NEB | c.2366A>T p.D789V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99425344; called by muse, mutect2, varscan2
- NIBAN1 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.922); catalogued as COSV100836465; called by muse, mutect2, varscan2
- OR1C1 | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as COSV101376250; called by muse, mutect2, varscan2
- OR2A12 | c.365A>G p.Y122C | Missense Mutation (SNP) | VAF 14/183 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.152); catalogued as COSV101283180; called by muse, mutect2
- OR3A1 | c.407G>C p.S136T | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.057); catalogued as COSV100041749; called by muse, mutect2, varscan2
- OR5B12 | c.424C>G p.L142V | Missense Mutation (SNP) | VAF 13/149 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.881); catalogued as COSV100222495, COSV56904373; called by muse, mutect2
- OR5F1 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99558754; called by muse, mutect2, varscan2
- OR5F1 | c.286G>C p.G96R | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99558757; called by muse, mutect2, varscan2
- OR5H6 | c.963C>A p.F321L (on ENST00000642105; = p.F305L on NM_001005479.2) | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101051797; called by muse, mutect2
- OXCT1 | c.1300A>G p.K434E | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.045); catalogued as rs748285289, COSV99542395; called by muse, mutect2, varscan2
- PADI3 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as rs760135960, COSV100968524; called by muse, mutect2, varscan2
- PCDHB8 | c.1796A>G p.Q599R | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99177160; called by muse, mutect2, varscan2
- PCDHGA6 | c.518G>T p.S173I | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV99542146; called by muse, mutect2, varscan2
- PHF8 | c.2453G>A p.R818Q (on ENST00000357988 / NM_001184896.1; = p.R782Q on NM_015107.3) | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs782358977, COSV100154536; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLAGL2 | c.1186C>T p.L396F | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as COSV99867408; called by muse, mutect2, varscan2
- PM20D1 | c.244T>C p.Y82H | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV100900217; called by muse, mutect2, varscan2
- POT1 | c.20C>T p.T7I | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV100714095; called by muse, mutect2, varscan2
- PPARG | c.486C>G p.F162L (on ENST00000287820 / NM_015869.5; = p.F132L on NM_005037.7) | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55143761, COSV55145690, COSV99826635; called by muse, mutect2, varscan2
- PROCR | c.338G>T p.R113L | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.155); catalogued as rs778433715, COSV53825823, COSV99405797; called by muse, mutect2, varscan2
- PRODH2 | c.716C>T p.A239V (on ENST00000301175; = p.A163V on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as rs760643122, COSV56558675, COSV99995383; called by muse, mutect2, varscan2
- PTGFR | c.541G>T p.A181S | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0.191); catalogued as COSV100882330; called by muse, mutect2, varscan2
- PTPRT | c.2662G>A p.G888R | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759474238, COSV61998414; called by muse, mutect2, varscan2
- RAB41 | c.665G>T p.C222F (on ENST00000374473 / NM_001363807.1; = p.C221F on NM_001032726.3) | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.124); catalogued as COSV99333773; called by muse, mutect2, varscan2
- RELN | c.10210C>T p.R3404C | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772932844, COSV100634218; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RTL5 | c.142G>T p.G48C | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV101030214; called by muse, mutect2
- RXFP1 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV100313968, COSV57046929; called by muse, mutect2, varscan2
- SCN10A | c.2691C>A p.N897K | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV101479464; called by muse, mutect2, varscan2
- SCP2D1 | c.443G>T p.R148M | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.02); catalogued as COSV99602137; called by muse, mutect2, varscan2
- SERPINA7 | c.1016C>G p.T339R | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as COSV100568392; called by muse, mutect2, varscan2
- SH3GL2 | c.108G>T p.M36I | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as COSV101014598; called by muse, mutect2, varscan2
- SLC28A3 | c.1503G>T p.W501C | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100883289, COSV100883350; called by muse, mutect2, varscan2
- SLC5A12 | c.1508C>G p.S503C | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101237722; called by muse, mutect2, varscan2
- SLIT2 | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as rs374199333; called by muse, mutect2, varscan2
- SLITRK2 | c.454G>T p.G152W | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100157960; called by muse, mutect2, varscan2
- SLITRK2 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100157961; called by muse, mutect2, varscan2
- SPANXN3 | c.14C>A p.T5N | Missense Mutation (SNP) | VAF 14/348 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100980824; called by muse, mutect2
- STON2 | c.2345G>C p.C782S (on ENST00000649389 / NM_001366849.2; = p.C725S on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/299 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99964938; called by muse, mutect2, varscan2
- SYNE3 | c.282G>A p.W94* | Nonsense Mutation (SNP) | VAF 12/61 reads (20%) | catalogued as COSV62080333; called by muse, mutect2, varscan2
- TAS2R38 | c.934C>A p.L312M | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1554444326, COSV101516473; called by muse, mutect2, varscan2
- TGFBI | c.1522G>A p.V508I | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100526602; called by muse, mutect2, varscan2
- TMPRSS15 | c.1118C>G p.T373S | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.303); catalogued as COSV99518512; called by muse, mutect2, varscan2
- TNN | c.1936G>A p.A646T | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.021); catalogued as rs200671106, COSV53420917; called by muse, mutect2, varscan2
- TNN | c.2788C>T p.P930S | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.119); catalogued as rs866848306, COSV99512420; called by muse, mutect2, varscan2
- TNRC6B | c.1720A>T p.T574S | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.952); catalogued as COSV100110037; called by muse, mutect2, varscan2
- TRIM22 | c.1154G>T p.G385V | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.967); catalogued as COSV101181416; called by muse, mutect2, varscan2
- TRMT1 | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99457128, COSV99457238; called by muse, mutect2, varscan2
- TRPM1 | c.3133T>A p.C1045S | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99856246; called by muse, mutect2
- TSPAN31 | c.122C>A p.S41Y | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99223684; called by muse, mutect2, varscan2
- TXNDC2 | c.205G>T p.V69F (on ENST00000306084 / NM_001098529.2; = p.V2F on NM_032243.6) | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV100046388; called by muse, mutect2
- USH2A | c.10273T>A p.C3425S | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV100238455; called by muse, mutect2, varscan2
- VN1R2 | c.788C>A p.A263E | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV100448064; called by muse, mutect2
- WDR72 | c.3048G>T p.M1016I | Missense Mutation (SNP) | VAF 11/199 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100854807; called by muse, mutect2
- WFS1 | c.2069G>A p.C690Y | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99901418, COSV99901688; called by muse, mutect2
- WWC2 | c.1129G>C p.E377Q | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV100968408; called by muse, mutect2, varscan2
- ZFYVE9 | c.1316G>T p.C439F | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99820362; called by muse, mutect2, varscan2
- ZNF587 | c.1600A>C p.S534R | Missense Mutation (SNP) | VAF 11/157 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.337); catalogued as COSV100299592; called by muse, mutect2
- ZNF644 | c.3298C>T p.R1100C | Missense Mutation (SNP) | VAF 36/242 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.365); catalogued as rs769317289, COSV61351116; called by muse, mutect2, varscan2
- ZNF804B | c.1630G>T p.D544Y | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1299601590, COSV60833995; called by muse, mutect2, varscan2
- CCDC70 | c.79del p.Q27Rfs*4 | Frame Shift Del (DEL) | VAF 27/69 reads (39%) | called by mutect2, pindel, varscan2
- KIF4A | c.3427del p.E1143Rfs*6 | Frame Shift Del (DEL) | VAF 25/110 reads (23%) | called by mutect2, pindel, varscan2
- LHX9 | c.313C>A p.L105I | Missense Mutation (SNP) | VAF 15/435 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2
- STK32B | c.792del p.K265Rfs*22 | Frame Shift Del (DEL) | VAF 23/82 reads (28%) | called by mutect2, pindel, varscan2
- ABCD2 | c.375T>A p.A125= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as COSV100429639; called by muse, mutect2, varscan2
- ACACB | c.1575G>T p.R525= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV100623088; called by muse, mutect2, varscan2
- ADAM33 | c.1947G>A p.E649= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as COSV100597974; called by muse, mutect2
- ADCY4 | c.612G>A p.R204= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV99353323; called by muse, mutect2
- AGT | c.309C>T p.A103= | Silent (SNP) | VAF 21/102 reads (21%) | catalogued as rs756049025, COSV100794435; called by muse, mutect2, varscan2
- ANKK1 | c.444G>T p.P148= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV100392950; called by muse, mutect2, varscan2
- ATP6V1A | c.690C>T p.G230= | Silent (SNP) | VAF 53/186 reads (28%) | catalogued as COSV99850232; called by muse, mutect2, varscan2
- AXDND1 | c.2277C>A p.S759= | Silent (SNP) | VAF 25/202 reads (12%) | catalogued as rs923137377, COSV62646704; called by muse, mutect2, varscan2
- CCDC71 | c.711G>A p.K237= | Silent (SNP) | VAF 13/122 reads (11%) | catalogued as rs1560085956, COSV100422396; called by muse, mutect2, varscan2
- CCKAR | c.345G>A p.K115= | Silent (SNP) | VAF 40/181 reads (22%) | catalogued as COSV99810396; called by muse, mutect2, varscan2
- DCAF8L1 | c.87A>T p.V29= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as COSV101491497; called by muse, mutect2, varscan2
- EFL1 | c.2115C>T p.V705= | Silent (SNP) | VAF 9/193 reads (5%) | catalogued as COSV99187690; called by muse, mutect2
- EPHA5 | c.354C>A p.I118= | Silent (SNP) | VAF 6/127 reads (5%) | catalogued as COSV99899986; called by muse, mutect2
- F5 | c.3543C>A p.V1181= | Silent (SNP) | VAF 12/315 reads (4%) | catalogued as COSV63121202; called by muse, mutect2
- FLNA | c.7140C>A p.V2380= (on ENST00000369850 / NM_001110556.2; = p.V2372= on NM_001456.3) | Silent (SNP) | VAF 39/153 reads (25%) | catalogued as COSV100774904; called by muse, mutect2, varscan2
- GPRASP1 | c.1560G>T p.S520= | Silent (SNP) | VAF 41/230 reads (18%) | catalogued as COSV100851031; called by muse, mutect2, varscan2
- MAGEB1 | c.174C>A p.P58= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV66775293, COSV66775926; called by muse, mutect2, varscan2
- NLRP10 | c.483G>A p.K161= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV100149815; called by muse, mutect2, varscan2
- OBSCN | c.3330T>C p.D1110= | Silent (SNP) | VAF 40/153 reads (26%) | catalogued as rs371731852; called by muse, mutect2, varscan2
- OFD1 | c.987G>A p.R329= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV100407013; called by muse, mutect2, varscan2
- OPLAH | c.1170A>T p.T390= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV101470794; called by muse, mutect2
- OR10P1 | c.162C>T p.A54= | Silent (SNP) | VAF 36/151 reads (24%) | catalogued as COSV100548193; called by muse, mutect2, varscan2
- OR10X1 | c.102T>C p.S34= | Silent (SNP) | VAF 34/180 reads (19%) | catalogued as COSV100936685; called by muse, mutect2, varscan2
- OR7D2 | c.504C>T p.F168= | Silent (SNP) | VAF 56/199 reads (28%) | catalogued as COSV100713032, COSV60139687; called by muse, mutect2, varscan2
- PCDHGA6 | c.303G>A p.R101= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as rs933509212, COSV99542145; called by muse, mutect2, varscan2
- PDE2A | c.1011C>T p.S337= | Silent (SNP) | VAF 31/108 reads (29%) | catalogued as rs1435099943, COSV100558194; called by muse, mutect2, varscan2
- PMS2 | c.1398C>T p.G466= | Silent (SNP) | VAF 66/156 reads (42%) | catalogued as rs752666485, COSV99764408; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- RPAP1 | c.837G>A p.E279= | Silent (SNP) | VAF 9/230 reads (4%) | catalogued as rs919806740, COSV100427219; called by muse, mutect2
- RTL9 | c.25C>A p.R9= | Silent (SNP) | VAF 73/312 reads (23%) | catalogued as COSV101511741; called by muse, mutect2, varscan2
- RYR2 | c.13008C>T p.D4336= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV100771855; called by muse, mutect2, varscan2
- SDK1 | c.3963G>T p.L1321= | Silent (SNP) | VAF 16/115 reads (14%) | catalogued as COSV101269599, COSV101269776; called by muse, mutect2, varscan2
- SLITRK2 | c.942A>T p.R314= | Silent (SNP) | VAF 11/158 reads (7%) | catalogued as COSV100157964; called by muse, mutect2
- SNAP25 | c.585C>T p.A195= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV99655085; called by muse, mutect2, varscan2
- SPTA1 | c.5208G>T p.V1736= | Silent (SNP) | VAF 29/188 reads (15%) | catalogued as COSV100935200; called by muse, mutect2, varscan2
- TIE1 | c.2478C>G p.P826= | Silent (SNP) | VAF 12/109 reads (11%) | called by muse, mutect2, varscan2
- TMEM67 | c.183G>T p.S61= | Silent (SNP) | VAF 37/176 reads (21%) | catalogued as COSV100019596; called by muse, mutect2, varscan2
- VIT | c.1746G>A p.L582= (on ENST00000389975 / NM_001177969.1; = p.L597= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as COSV101007568; called by muse, mutect2, varscan2
- ZHX1 | c.2004A>T p.T668= | Silent (SNP) | VAF 17/126 reads (13%) | catalogued as COSV99933778; called by muse, mutect2, varscan2
- BTN2A3P | n.102C>T | RNA (SNP) | VAF 19/90 reads (21%) | called by muse, mutect2, varscan2
- MIR106A | n.7C>T | RNA (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
